Surgical pathology report (de-identified scan), TCGA case TCGA-F7-8489, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Asterand, specimen TCGA-F7-8489-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]

[REDACTED] Case ID	Gross Description	Microscopic Description	Diagnosis Details
[REDACTED]			

[page 2 of 3]
Comments	Formatted Path Report
	Specimen type: Floor of mouth Tumor size (in cm): 3 x 3 x 2 Histologic type: Squamous cell carcinoma [REDACTED]

[REDACTED]	ID
[REDACTED]	

[page 3 of 3]
Excision date	Laterality
	Midline

Source: NCI Genomic Data Commons file b24982a6-29cd-42e6-a9d0-a4f79114d798 (TCGA-F7-8489.016F47F9-9EB5-4A74-AA85-C60B6B87643F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).